Somatic mutation profile of tumor specimen TCGA-06-0210-01B (aliquot TCGA-06-0210-01B-01D-1491-08) from TCGA case TCGA-06-0210, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 72.8 years (26,600 days).
Specimen TCGA-06-0210-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 565f8dbb-2755-4ee1-a44e-6d661b37d405.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0210-10A (Blood Derived Normal), aliquot TCGA-06-0210-10A-01D-1491-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e46c7ee-20a0-4555-8a69-efa59d673b72

The open-access MAF lists 61 somatic variants for this specimen: 49 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 10, Nonsense Mutation 3, Splice Site 1, Intron 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.1901C>T p.A634V | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as rs121964878, CM034217, COSV55730231; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HEXA | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121907957, CM920330, COSV51507319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- NF1 | c.574C>T p.R192* | Nonsense Mutation (SNP) | VAF 12/72 reads (17%) | catalogued as rs397514641, CM000774, COSV62197492; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 23/140 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTL9 | c.1138G>A p.V380I | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs532021673, COSV61005106; called by muse, mutect2, varscan2
- ADCY1 | c.1912C>G p.L638V | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV52043265; called by muse, mutect2, varscan2
- AP3D1 | c.2968G>A p.V990M | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs780575228, COSV61433351; called by muse, mutect2, varscan2
- ARFGAP2 | c.305C>G p.A102G | Missense Mutation (SNP) | VAF 66/356 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.485); catalogued as COSV54068072; called by muse, mutect2, varscan2
- ARHGEF28 | c.913A>G p.I305V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs1260665167, COSV55271556; called by muse, mutect2, varscan2
- ATP2B3 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 65/309 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs200641356, COSV54848455; called by muse, mutect2, varscan2
- BFSP1 | c.641C>T p.T214M | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.086); catalogued as rs577981820, COSV64899369; called by muse, mutect2, varscan2
- CAMSAP2 | c.616C>G p.H206D | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV52671219; called by muse, mutect2, varscan2
- CHD5 | c.3458C>T p.S1153L | Missense Mutation (SNP) | VAF 42/161 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1351642953, COSV52415446; called by muse, mutect2, varscan2
- CPNE8 | c.790G>A p.V264I | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as rs926258147, COSV58838522; called by muse, mutect2, varscan2
- CPZ | c.647G>A p.S216N (on ENST00000360986 / NM_001014447.3; = p.S205N on NM_003652.3) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1198416310, COSV59926275, COSV59926457, COSV59926554; called by muse, mutect2
- CTNNA2 | c.203C>G p.T68S | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as COSV100781182, COSV63570327; called by muse, mutect2, varscan2
- DNAJC6 | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as rs761817101, COSV54775600; called by muse, mutect2, varscan2
- EVPL | c.3355C>T p.R1119C | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs770411485, COSV56916558; called by muse, mutect2, varscan2
- F5 | c.1976-2A>C p.X659_splice | Splice Site (SNP) | VAF 18/88 reads (20%) | catalogued as COSV63122920, COSV63124448; called by muse, mutect2, varscan2
- FGD1 | c.422C>A p.T141N | Missense Mutation (SNP) | VAF 48/241 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.134); catalogued as COSV64308781; called by muse, mutect2, varscan2
- FKBP6 | c.697G>C p.D233H | Missense Mutation (SNP) | VAF 43/193 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV52720128, COSV52720387; called by muse, mutect2, varscan2
- GCK | c.962C>G p.S321C | Missense Mutation (SNP) | VAF 37/212 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV60788282; called by muse, mutect2, varscan2
- GFRAL | c.194A>G p.Y65C | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.049); catalogued as rs1475878119, COSV61235918; called by muse, varscan2
- INHBA | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 32/280 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54219953; called by muse, mutect2, varscan2
- KASH5 | c.445G>T p.G149C | Missense Mutation (SNP) | VAF 58/292 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV71358030; called by muse, mutect2, varscan2
- KIF26A | c.3884G>A p.R1295H | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV59470954; called by muse, mutect2
- MS4A1 | c.569T>A p.F190Y | Missense Mutation (SNP) | VAF 50/207 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.394); catalogued as COSV61942160; called by muse, mutect2, varscan2
- MUC3A | c.443C>T p.T148M | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated, low confidence (0.17); catalogued as rs781659697, COSV60212876; called by muse, mutect2, varscan2
- OR52R1 | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.218); catalogued as rs200440576; called by muse, mutect2, varscan2
- PCDHGB3 | c.302C>T p.T101M | Missense Mutation (SNP) | VAF 89/417 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.041); catalogued as COSV54042465; called by muse, mutect2, varscan2
- PCSK2 | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 41/228 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1199393951, COSV52733336; called by muse, mutect2, varscan2
- PRDM9 | c.2483G>T p.G828V | Missense Mutation (SNP) | VAF 31/241 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57013266, COSV57013946; called by muse, mutect2, varscan2
- PRPF38A | c.804C>G p.S268R | Missense Mutation (SNP) | VAF 43/229 reads (19%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.985); catalogued as COSV57123398; called by muse, mutect2, varscan2
- REPIN1 | c.1466G>T p.C489F | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68292287, COSV68292360; called by muse, mutect2, varscan2
- REPS2 | c.1849C>T p.R617C | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58188699; called by muse, mutect2, varscan2
- RNF17 | c.4172C>T p.S1391L | Missense Mutation (SNP) | VAF 35/191 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747304860, COSV55041145; called by muse, mutect2, varscan2
- RYR1 | c.14911A>G p.T4971A | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as rs756040490, COSV62112186; called by muse, mutect2, varscan2
- SEMA3F | c.425G>T p.C142F | Missense Mutation (SNP) | VAF 55/295 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50037126; called by muse, mutect2, varscan2
- SERPINA3 | c.1219G>A p.D407N | Missense Mutation (SNP) | VAF 40/267 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV67586813; called by muse, mutect2, varscan2
- SLC30A3 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 49/271 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1343110597, COSV51988244; called by muse, mutect2, varscan2
- SPTA1 | c.2671C>T p.R891* | Nonsense Mutation (SNP) | VAF 71/361 reads (20%) | catalogued as rs755630903, CM148356, COSV63749670; called by muse, mutect2, varscan2
- STXBP5L | c.1672C>T p.R558* | Nonsense Mutation (SNP) | VAF 19/155 reads (12%) | catalogued as rs1388311069, COSV56523458; called by muse, mutect2, varscan2
- TMC4 | c.1236G>T p.K412N (on ENST00000617472 / NM_001145303.3; = p.K406N on NM_144686.4) | Missense Mutation (SNP) | VAF 43/217 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV55827311; called by muse, mutect2, varscan2
- TNN | c.628G>A p.G210S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1316855469, COSV53436684, COSV99513658; called by muse, mutect2
- VPS50 | c.403A>G p.I135V | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.956); catalogued as rs769084619, COSV52495042; called by muse, mutect2, varscan2
- ZNF483 | c.1013C>G p.P338R | Missense Mutation (SNP) | VAF 52/196 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as COSV58515814; called by muse, mutect2, varscan2
- IGKV1D-16 | c.223A>T p.S75C | Missense Mutation (SNP) | VAF 72/360 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- NF1 | c.1897del p.D633Ifs*55 | Frame Shift Del (DEL) | VAF 24/191 reads (13%) | called by mutect2, pindel, varscan2
- CASK | c.6C>T p.A2= | Silent (SNP) | VAF 43/149 reads (29%) | catalogued as COSV59367194; called by muse, mutect2, varscan2
- CYP2F1 | c.1017G>A p.A339= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as rs771083555, COSV58528960; called by muse, mutect2, varscan2
- HCAR1 | c.384C>T p.S128= | Silent (SNP) | VAF 60/262 reads (23%) | catalogued as COSV63674676; called by muse, mutect2, varscan2
- KIF13A | c.2316C>A p.L772= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV52466957; called by muse, mutect2, varscan2
- LCK | c.486G>A p.S162= | Silent (SNP) | VAF 29/115 reads (25%) | catalogued as rs1126767; called by muse, mutect2, varscan2
- LRWD1 | c.409C>T p.L137= | Silent (SNP) | VAF 28/185 reads (15%) | catalogued as rs1563653319, COSV52962392; called by muse, mutect2, varscan2
- PPP1R3B | c.495G>A p.T165= | Silent (SNP) | VAF 53/279 reads (19%) | catalogued as rs138887555; called by muse, mutect2, varscan2
- SPTA1 | c.3645G>C p.L1215= | Silent (SNP) | VAF 39/243 reads (16%) | catalogued as COSV63760296; called by muse, mutect2, varscan2
- STAB1 | c.4707C>T p.C1569= | Silent (SNP) | VAF 32/178 reads (18%) | catalogued as rs375629208; called by muse, mutect2, varscan2
- THSD7A | c.2925A>T p.P975= | Silent (SNP) | VAF 55/301 reads (18%) | catalogued as rs79441692, COSV70273650; called by muse, mutect2, varscan2
- CCDC33 | c.2139+76G>A | Intron (SNP) | VAF 55/233 reads (24%) | catalogued as COSV51432317; called by muse, mutect2, varscan2
- ZNF271P | n.1012T>G | RNA (SNP) | VAF 19/81 reads (23%) | called by muse, mutect2, varscan2
